Somatic mutation profile of tumor specimen C3L-06081-54 (aliquot CPT0452610002) from CPTAC case C3L-06081, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 22.1 years (8,068 days).
Specimen C3L-06081-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ca6e72-21c6-42e6-87d8-de3ef211f6a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06081-50 (Buccal Cell Normal), aliquot CPT0452580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8788590-c771-48d3-81ce-78ceafa95a6a

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 34/166 reads (20%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, varscan2
- RNF123 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs770997519, COSV59691901; called by muse, mutect2, varscan2
- TNIP3 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs746493432, COSV50249820, COSV50255809; called by muse, mutect2
- UBA2 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 49/245 reads (20%) | catalogued as COSV55830677; called by muse, mutect2, varscan2
- ANK3 | c.4577G>T p.S1526I | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARHGAP36 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DST | c.8591T>A p.L2864H | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETV6 | c.1032_1033insAT p.V345Mfs*27 | Frame Shift Ins (INS) | VAF 43/245 reads (18%) | called by mutect2, pindel, varscan2
- LRP4 | c.4577C>A p.T1526N | Missense Mutation (SNP) | VAF 204/457 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMD8 | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- PTPRM | c.2558G>A p.S853N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MYH11 | c.4981C>T p.L1661= | Silent (SNP) | VAF 228/507 reads (45%) | called by muse, varscan2
- TDO2 | c.232+55G>A | Intron (SNP) | VAF 61/123 reads (50%) | catalogued as rs558732231, COSV72233188; called by muse, mutect2, varscan2
- TRIM49D1 | c.*40C>T | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
